Gene-level copy-number profile of tumor specimen ALCH-B1S0-TTP1-A from ALCHEMIST case ALCH-B1S0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.5 years (25,748 days).
Specimen ALCH-B1S0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6b67c7a5-536e-4a40-b5ea-ae8978b4e174.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1S0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/33c13d2a-5e1c-4d6a-a4da-5f139ac1edbc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 25; copy number 2: 3,806; copy number 3: 1,083; copy number 4: 20,980; copy number 5: 4,114; copy number 6: 18,582; copy number 7: 2,208; copy number 8: 3,907; copy number 9: 1,943; copy number 10: 1,608; copy number 11: 93; copy number 12: 26; copy number 13: 1; copy number 14: 4; copy number 15: 1; copy number 19: 3; copy number 26: 4; copy number 30: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:22,893,692–22,893,818, 1 gene (within-gene range 0–5): IGLJ1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,683 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–1,470,163, 118 genes, copy number 9–10 (broad region; genes not listed).
- chr1:182,096,338–182,314,061, 1 gene, copy number 10 (within-gene range 6–10): LINC01344.
- chr1:182,182,730–182,336,334, 4 genes, copy number 10: YPEL5P1, RNU6-152P, AL513480.1, EIF1P3.
- chr3:93,843,764–177,228,000, 1,294 genes, copy number 9–10 (broad region; genes not listed).
- chr3:177,337,628–198,123,232, 457 genes, copy number 9 (broad region; genes not listed).
- chr4:10,238,213–10,238,235, 1 gene, copy number 11: AC006499.8.
- chr4:46,993,723–49,246,915, 39 genes, copy number 10–11 (within-gene range 4–11): GABRB1, AC107398.3, COMMD8, AC107398.4, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr4:56,049,073–58,118,070, 43 genes, copy number 9: CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, SRIP1, AC096725.1.
- chr5:35,429,064–36,242,279, 17 genes, copy number 11 (within-gene range 4–11): U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2.
- chr5:40,512,333–42,721,878, 28 genes, copy number 11: TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1.
- chr5:43,192,071–43,412,391, 8 genes, copy number 12: NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28.
- chr5:135,802,985–135,803,075, 1 gene, copy number 14: MIR5692C1.
- chr5:150,950,109–150,979,175, 2 genes, copy number 9: AC022106.1, AC022106.2.
- chr6:51,385,282–51,464,765, 3 genes, copy number 11: AL158050.2, AL158050.1, AL365219.1.
- chr6:73,695,785–74,004,812, 3 genes, copy number 9–12 (within-gene range 4–12): CD109, AL590552.1, TXNP7.
- chr7:6,663,974–39,888,664, 541 genes, copy number 9 (broad region; genes not listed).
- chr7:62,275,361–62,275,678, 1 gene, copy number 10: AC128676.1.
- chr7:76,650,401–76,919,191, 3 genes, copy number 9: AC004980.2, AC006972.1, AC007003.1.
- chr7:76,968,197–77,004,308, 3 genes, copy number 9 (within-gene range 7–9): FDPSP7, AC114737.1, DTX2P1.
- chr7:98,846,488–99,207,506, 8 genes, copy number 9: TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7.
- chr7:99,546,300–99,820,086, 13 genes, copy number 11–12: FAM200A, ZNF655, AC005020.2, TMEM225B, ZSCAN25, AC005020.1, CYP3A5, CYP3A7-CYP3A51P, CYP3A51P, CYP3A7, CYP3A4, AC069294.1, CYP3A137P.
- chr7:102,681,836–105,399,308, 46 genes, copy number 10: RASA4DP, FAM185A, AC105052.2, FBXL13, RNU6-1136P, RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86, ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P.
- chr7:105,532,169–152,436,003, 907 genes, copy number 9–10 (within-gene range 6–12) (broad region; genes not listed).
- chr7:152,644,776–159,233,377, 92 genes, copy number 9 (broad region; genes not listed).
- chr11:1,012,823–1,055,749, 2 genes, copy number 11: MUC6, LINC02688.
- chr11:1,995,176–2,001,470, 4 genes, copy number 26: H19, AC051649.3, MIR675, AC051649.2.
- chr11:48,907,103–48,908,946, 1 gene, copy number 10: AC027369.5.
- chr13:112,313,467–112,321,758, 1 gene, copy number 15: LINC01043.
- chr14:18,418,775–18,419,273, 1 gene, copy number 13: BNIP3P6.
- chr14:23,619,201–23,729,757, 3 genes, copy number 9: AL135999.3, DHRS2, AL160237.1.
- chr14:61,529,128–61,658,696, 4 genes, copy number 12 (within-gene range 8–12): AL355916.3, AL355916.2, LINC01303, AL355916.1.
- chr16:2,603,350–2,682,379, 5 genes, copy number 9–30: AC141586.1, PDPK2P, AC141586.4, AC141586.2, ERVK13-1.
- chr16:2,752,626–2,805,304, 6 genes, copy number 9–11: SRRM2, ELOB, AC092117.1, PRSS33, SNORA3C, PRSS41.
- chr17:34,255,218–34,332,228, 5 genes, copy number 9: CCL2, CCL7, CCL11, CCL8, AC011193.2.
- chr19:1,103,926–1,106,791, 1 gene, copy number 9: GPX4.
- chr19:1,259,384–1,279,244, 3 genes, copy number 12: CIRBP, CIRBP-AS1, FAM174C.
- chr19:1,438,358–1,479,219, 5 genes, copy number 10–14 (within-gene range 10–17): RPS15, AC027307.3, APC2, AC027307.2, C19orf25.
- chr19:27,638,483–27,646,483, 2 genes, copy number 9: ERVK-28, AC112702.1.
- chr19:41,425,359–41,442,392, 4 genes, copy number 11 (within-gene range 6–11): AC011462.2, B3GNT8, DMAC2, Metazoa_SRP.
- chr21:8,603,547–8,680,934, 2 genes, copy number 9: RPSAP68, CR381572.2.

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
